Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RK, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RK-02A (Recurrent Tumor).

ICD-O-3
Oligoastrocytoma, grade II 9882/3
Site: ^{CNS}Supratentorial Brain NOS
^{path}Brain, frontal lobe C71.0
C71.1
11/29/14

Nature of material: Brain
Biopsy number:

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Received in formalin an irregular fragment of brain, measuring 4.5 x 2.5 x 1.5 cm and weighing in at 7g. Shows congested vasculature with brown and friable areas.

MICROSCOPY

H & E sections show residual infiltrative glial neoplasm, permeating nervous tissue of the neocortex and white matter. The tumor is hypercellular and composed of hyperchromatic nuclei cell proliferation with mild pleomorphism and rare mitotic figures. The cytoplasm sometimes is clear and sparse and sometimes shows "minigemistocystic" phenotype. Are still observed cystic areas with former hemorrhage in the neoplasia sinuses, which is richly vascularized by capillaries with mild endothelial proliferation. No areas of necrosis were observed. The tumor shows rare mitotic figures. The tumor showed negative immunostaining for galectin-3.

DIAGNOSTIC

Excision product of residual brain tumor (frontal):

- Oligoastrocytoma, grade II (WHO).
- The tumor shows cell proliferation index assessed by antibody MIB-1 less than 1% of nuclear positivity.

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

Recurrence 1 of 2, for primary
grade II LGG. BCR

Source: NCI Genomic Data Commons file a24a8382-4902-4b35-aeb4-fbac04c17437 (TCGA-TQ-A7RK.54B8D3A8-68BB-4C6D-8428-D495B6DB2622.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).